Surgical pathology report (de-identified scan), TCGA case TCGA-Z4-AAPF, project TCGA-SARC (Sarcoma), tissue source site Cureline, specimen TCGA-Z4-AAPF-01A (Primary Tumor).

Case #

Patient: Age (years): Gender: F

Clinical diagnosis: Sarcoma

Date of procurement: (mm/dd/yyyy)

Sample:

Gross description: Fibrous synovial tissue measured 2x1x1 cm with from arm joint 1 cm thick.. Section shows tumor mass in tissue.

Microscopic description: Sections reveal tumor mass with malignant synovioma. Surgical margins are clear. Histology consistent with well-differentiated synovial sarcoma, Grade 3
5 lymph nodes were studies, all negative

Final diagnosis: Synovial sarcoma

ICD-O-3
Sarcoma, synovial NOS 9040/3
Arm NOS C49.1
JW 4/22/14

Confidential

Source: NCI Genomic Data Commons file 56c25f29-11f1-4364-9780-8cd5946ab434 (TCGA-Z4-AAPF.FB37EC44-4F18-4A28-B79A-98918BEB5D81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).